Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A3CG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A3CG-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

carcinoma, hepatocellular, NOS 8170/3

Site: liver C22.0

lw 10/15/11

MRN:

PHN:

ACB:

DOB/Gender:

Telephone:

Encounter:

Accession Number:

Collected Date:

Pathologist:

Specimen Description

- A. Gallbladder
- B. Liver tumor - QS
- C. Liver tumor - 26 g

Clinical Information

Cirrhosis, hepatitis, liver tumor.

Diagnosis

A: Gallbladder, Cholecystectomy:

- Chronic cholecystitis and cholelithiasis (please see microscopic description)

B: Liver, Liver Tumor, Biopsy:

- Hepatocellular carcinoma

C: Liver, Liver Tumor, Resection:

- Hepatocellular carcinoma, moderately differentiated
- Trabecular and pseudoglandular morphology with areas of clear cells
- Tumor size 2.5 cm in greatest dimension
- Positive resection margin
- Lymphovascular invasion is not identified

Co:

Qual/Synch/omus Primary Notes		X

lw 10/15/11

Pathology: Provider

[page 2 of 4]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

- Uninvolved liver with cirrhosis and extensive lymphocytic inflammation and steatosis
- Clinical history of hepatitis C
- Please see synoptic report

Synoptic Report

C: Liver, Resection, Microscopic

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

PRIMARY TUMOR (pT):

pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin involved by invasive carcinoma

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Cirrhosis/fibrosis

Gross Description

Received are specimens A to C. All requisitions and specimen containers are labelled with the patient's name

*The cassettes and AP identifiers are labelled with the Surgical Number

Cc:

[page 3 of 4]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

A. The specimen is received fresh and is subsequently placed into formalin and consists of an intact gallbladder measuring 8.3 x 4.2 x 1.5 cm. The serosal surface is tan, smooth and glistening and the adventitial surface is tan and roughened. The cystic duct resection margin is identified and is patent. The cystic duct lymph node is not grossly identified. Multiple tan/green friable calculi are identified in the lumen measuring 0.9 x 0.6 x 0.3 cm in aggregate. The mucosal surface is green and slightly velvety with yellow speckling. The wall thickness of the gallbladder ranges from 0.1 to 0.6 cm. Specimen serially sectioned and representative sections are submitted in cassettes A1 and A2, cassette A1 representing the cystic duct resection margin and sections from the neck, body and fundus, and A2 representing further sections from the thickened wall.

B. The specimen consists of a 1 cm long core of yellow tissue which is submitted in toto for QS.

C. The specimen is received fresh and is subsequently placed into formalin and consists a portion of liver weighing 26 grams and measuring 5.5 x 3.5 x 3.0 cm. The resection margin is marked with blue dye. The serosal surface of the liver has a congested and slightly nodular appearance. A tan and lobular lesion is identified on the cut surface and extends up to the blue-inked resection margin as well as to the serosal surface. This mass measures 3.5 x 3.1 x 2.8 cm.

Sections are submitted as follows:

C1-C2 contiguous sections bisected representing the mass in relationship with the blue-inked resection margin and the serosal surface

C3 lesion and blue-inked resection margin at the pleural surface

C4-C6 further representative sections from the lesion and grossly unremarkable parenchyma

Please note a portion of the specimen is submitted for tumor banking.

Frozen Section Diagnosis

B. Liver Tumor:

- Hepatocellular carcinoma

Reported by:

Microscopic Description

A. Microscopic sections show a focal granuloma within the wall of the gallbladder. The granuloma has foamy histiocytes. Further levels of this section lose this are. The granuloma is most likely consistent to a foreign body reaction which is commonly seen as a lipid granuloma.

CC:

[page 4 of 4]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

C: Microscopic sections show an ill-defined mass arising in the liver. The architecture of the mass includes a trabecular, solid, and pseudoglandular areas. There are also areas of clear cell change. The trabecular plates are greater than four cells thick in areas. There is hemorrhage that surrounds the tumor, as well as a focal area of infarct. The mass is present at the surgical resection margin. The nuclear features of the hepatocellular carcinoma include higher N/C ratio with hyperchromatic nuclei and pleomorphism. The cytoplasm, in areas, is strongly eosinophilic, while in others, shows a clear cell change. Immunostains are pending.

The uninvolved liver shows a cirrhotic pattern. There are nodules of hyperplastic hepatocytes surrounded by fibrous septae that are heavily inflamed. The portal tracts are present and occasionally involved by a periportal lymphocytic inflammation. Steatosis is also identified. Special stains illustrate the fibrosis surrounding the nodules consistent with cirrhosis. The reticulin stains show loss of the two cell thick hepatocyte plates. There is no hemosiderin or PAS diastase resistant inclusions identified.

Cc:

Source: NCI Genomic Data Commons file e586c277-6805-4a1a-9270-ac84a2bb8b80 (TCGA-G3-A3CG.6E2F9CE1-6D48-42DF-8737-64ED53BF8646.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).